Somatic mutation profile of tumor specimen 0DWYWK from CCDI case PBCPJV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 16.4 years (5,988 days).
Specimen 0DWYWK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6e48fc5-1a8a-4772-880e-4a9106ccd198.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWYUS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4312aa32-9cc3-44d3-bb2d-f1600cd08f12

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, 5'UTR 2, Silent 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BSN | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 259/525 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.296); catalogued as rs372598293, COSV56528908; called by muse, mutect2, varscan2
- NMNAT2 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 34/1406 reads (2%) | SIFT tolerated (0.18); PolyPhen benign (0.14); catalogued as COSV54272453; called by muse, mutect2
- SCN11A | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 281/610 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759631305, COSV56566690; called by muse, mutect2, varscan2
- SLC10A5 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 28/1010 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1195263022; called by muse, mutect2
- DDX60L | c.827A>C p.H276P | Missense Mutation (SNP) | VAF 27/824 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); called by muse, mutect2
- FAM189B | c.710A>C p.D237A | Missense Mutation (SNP) | VAF 240/796 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KNG1 | c.655A>C p.K219Q | Missense Mutation (SNP) | VAF 308/763 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- PCSK2 | c.1801G>A p.D601N | Missense Mutation (SNP) | VAF 139/577 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, varscan2
- RABGAP1L | c.2005C>A p.Q669K | Missense Mutation (SNP) | VAF 260/873 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TATDN2 | c.2223T>G p.D741E | Missense Mutation (SNP) | VAF 303/724 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TOMM5 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 281/607 reads (46%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ESPL1 | c.3501G>A p.T1167= | Silent (SNP) | VAF 196/611 reads (32%) | catalogued as rs756999630; called by muse, mutect2, varscan2
- VPS18 | c.2568C>T p.C856= | Silent (SNP) | VAF 118/236 reads (50%) | catalogued as rs144742197; called by muse, mutect2, varscan2
- DCHS2 | n.3201G>A | RNA (SNP) | VAF 324/740 reads (44%) | catalogued as rs765655550; called by muse, mutect2, varscan2
- LRRTM1 | c.-49G>T | 5'UTR (SNP) | VAF 172/462 reads (37%) | catalogued as rs751326524; called by muse, mutect2, varscan2
- PLPP6 | c.-30C>T | 5'UTR (SNP) | VAF 48/97 reads (49%) | called by muse, mutect2, varscan2
- SLC13A1 | c.*40A>G | 3'UTR (SNP) | VAF 137/311 reads (44%) | called by muse, mutect2, varscan2
